Somatic mutation profile of tumor specimen TCGA-DV-5574-01A (aliquot TCGA-DV-5574-01A-01D-1534-10) from TCGA case TCGA-DV-5574, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 37.0 years (13,517 days).
Specimen TCGA-DV-5574-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c77fdb6c-a73a-4a66-b83d-ea96d5dfec82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DV-5574-10A (Blood Derived Normal), aliquot TCGA-DV-5574-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4e34954-0e9f-4520-bbe8-06b61d4891fd

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Intron 2, Splice Region 1, Nonsense Mutation 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RPGR | c.2520+1548G>T | Intron (SNP) | VAF 35/218 reads (16%) | catalogued as rs1555961220, COSV58836726; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AVIL | c.251A>T p.D84V | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57682432; called by muse, mutect2, varscan2
- BAZ2B | c.1969G>T p.D657Y | Missense Mutation (SNP) | VAF 33/882 reads (4%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.75); catalogued as COSV58610990; called by muse, mutect2
- BPIFB6 | c.1018A>C p.M340L | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV62755700; called by muse, mutect2, varscan2
- CNTN6 | c.223T>C p.Y75H | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.776); catalogued as COSV63177461; called by muse, varscan2
- CUL3 | c.142A>T p.N48Y | Missense Mutation (SNP) | VAF 45/526 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52366402; called by muse, mutect2
- DAW1 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 30/245 reads (12%) | catalogued as COSV59366543, COSV59367655; called by muse, mutect2, varscan2
- DICER1 | c.390T>A p.N130K | Missense Mutation (SNP) | VAF 82/762 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as rs747882352, COSV58622779; called by muse, mutect2, varscan2
- KIF4B | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1481965337, COSV70527979; called by muse, mutect2
- MAGEC1 | c.2101G>A p.G701R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.262); catalogued as rs866835044, COSV53575722; called by muse, mutect2
- NOXA1 | c.260+1G>A p.X87_splice | Splice Site (SNP) | VAF 16/82 reads (20%) | catalogued as COSV58162496; called by muse, mutect2, varscan2
- PALB2 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 38/379 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55166685; called by muse, mutect2
- PNP | c.162del p.N55Tfs*19 | Frame Shift Del (DEL) | VAF 24/225 reads (11%) | catalogued as COSV100829014; called by mutect2, varscan2
- RFX5 | c.354G>T p.R118= | Splice Region (SNP) | VAF 8/92 reads (9%) | catalogued as COSV51839889; called by muse, mutect2
- SYN3 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60510716; called by muse, mutect2, varscan2
- UBR5 | c.7703T>A p.F2568Y | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV55291489; called by muse, mutect2, varscan2
- CCDC3 | c.450C>A p.N150K | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- GIPC1 | c.377A>G p.H126R | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MEP1A | c.847A>C p.T283P | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.159); called by muse, mutect2
- SULT1A1 | c.553A>T p.T185S | Missense Mutation (SNP) | VAF 16/289 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2
- NSMCE1 | c.57C>T p.L19= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- PLEKHA3 | c.786C>T p.H262= | Silent (SNP) | VAF 40/308 reads (13%) | catalogued as rs139167699; called by muse, mutect2, varscan2
- SBDS | c.726A>G p.V242= | Silent (SNP) | VAF 130/742 reads (18%) | catalogued as rs772620554, COSV55888008; called by muse, mutect2, varscan2
- SBF2 | c.2382T>G p.A794= | Silent (SNP) | VAF 40/363 reads (11%) | catalogued as COSV56302792; called by muse, mutect2
- TSPAN8 | c.465C>T p.V155= | Silent (SNP) | VAF 69/633 reads (11%) | catalogued as COSV56078387; called by muse, mutect2, varscan2
- CCM2 | c.31-10499T>G | Intron (SNP) | VAF 53/266 reads (20%) | catalogued as COSV51849351; called by muse, mutect2, varscan2
